Somatic mutation profile of tumor specimen 0DV992 from CCDI case PBCLZN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.1 years (1,514 days).
Specimen 0DV992: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a09f7988-4d3c-4886-a86e-377daaf89cf3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV98O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3290ef21-2960-4de9-87db-6b96458081be

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Intron 3, Silent 2, 5'UTR 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHAT | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 118/346 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs200176236, COSV60319829; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD7 | c.8267C>G p.T2756R | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as CD112416; called by muse, mutect2, varscan2
- FTMT | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 81/216 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs368526431; called by muse, mutect2, varscan2
- KDM6B | c.3424G>A p.V1142I | Missense Mutation (SNP) | VAF 100/203 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.087); catalogued as rs150711335; called by muse, mutect2, varscan2
- MROH2B | c.4141G>A p.V1381M | Missense Mutation (SNP) | VAF 157/460 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV68182568; called by muse, mutect2, varscan2
- OR4K15 | c.323A>G p.D108G (on ENST00000305051; = p.D84G on NM_001005486.1) | Missense Mutation (SNP) | VAF 37/426 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV100521061; called by muse, mutect2
- PTPRD | c.5494G>C p.E1832Q | Missense Mutation (SNP) | VAF 161/478 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs778346779, COSV61947861; called by muse, mutect2, varscan2
- RBMXL3 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 83/186 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.713); catalogued as rs782060490, COSV57749302; called by muse, mutect2, varscan2
- SPON1 | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 169/378 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs781875870, COSV59963307; called by muse, mutect2, varscan2
- CACNA1F | c.1265A>T p.D422V | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2
- ERF | c.558dup p.S187Qfs*2 | Frame Shift Ins (INS) | VAF 50/153 reads (33%) | called by mutect2, varscan2
- FPR3 | c.807A>T p.K269N | Missense Mutation (SNP) | VAF 23/473 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.133); called by muse, mutect2
- HCFC1 | c.3113G>C p.G1038A | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- HES6 | c.155T>C p.L52P | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2
- IGF2BP2 | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 98/286 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PARP4 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 27/530 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- THADA | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 22/651 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, mutect2
- TRPM5 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.01); called by muse, mutect2
- MAGEA3 | c.786C>T p.P262= | Silent (SNP) | VAF 16/212 reads (8%) | catalogued as rs368605065; called by muse, mutect2
- PTPN2 | c.195G>A p.E65= | Silent (SNP) | VAF 22/640 reads (3%) | called by muse, mutect2
- ARHGEF12 | c.2226-98A>C | Intron (SNP) | VAF 7/95 reads (7%) | called by muse, mutect2
- GALNT9 | c.*39C>T | 3'UTR (SNP) | VAF 17/66 reads (26%) | catalogued as rs778456882, COSV100201591; called by muse, mutect2, varscan2
- LY6H | c.68-64G>A | Intron (SNP) | VAF 11/64 reads (17%) | catalogued as rs558870056; called by muse, mutect2, varscan2
- NKPD1 | c.662-36T>A | Intron (SNP) | VAF 6/49 reads (12%) | catalogued as rs1028282600; called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 26/200 reads (13%) | called by muse, varscan2
